Somatic mutation profile of tumor specimen TCGA-ZH-A8Y8-01A (aliquot TCGA-ZH-A8Y8-01A-51D-A417-09) from TCGA case TCGA-ZH-A8Y8, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.2 years (26,744 days).
Specimen TCGA-ZH-A8Y8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e326ec8a-f407-40bb-85ae-0cfd784c71ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZH-A8Y8-10A (Blood Derived Normal), aliquot TCGA-ZH-A8Y8-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/460a0da3-7395-4d1b-854e-54fba50594fa

The open-access MAF lists 32 somatic variants for this specimen: 24 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 7, Frame Shift Del 3, Nonsense Mutation 2, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 7/37 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as rs121913238, COSV55502066, COSV55502677; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRDT | c.112G>C p.V38L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV61771648; called by muse, mutect2, varscan2
- CEP68 | c.2024T>C p.I675T | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1272890582; called by muse, mutect2, varscan2
- CSMD3 | c.1108G>A p.V370I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.021); catalogued as rs112359948; called by muse, mutect2, varscan2
- DENND2B | c.408G>C p.Q136H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100567569; called by muse, mutect2, varscan2
- FLT3 | c.2546G>A p.R849H | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201923726, COSV54049041; called by muse, mutect2, varscan2
- HNRNPK | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV57937260; called by muse, mutect2
- KEAP1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.306); catalogued as COSV50632719; called by muse, mutect2, varscan2
- SEMA5A | c.2426G>A p.R809H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1213488683; called by muse, mutect2, varscan2
- SMIM19 | c.157A>C p.I53L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.927); catalogued as rs750356937; called by muse, mutect2, varscan2
- SRSF8 | c.185T>C p.F62S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1555107007; called by muse, mutect2, varscan2
- WNT10B | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as rs763451340, COSV56404806, COSV56405396; called by muse, mutect2, varscan2
- ARID1B | c.3867del p.N1290Tfs*145 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | called by mutect2, pindel, varscan2
- ENGASE | c.359G>A p.S120N | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- ESYT2 | c.1062_1066del p.I355Kfs*16 (on ENST00000613624; = p.I279Kfs*16 on NM_020728.3) | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- OLFM3 | c.541T>C p.S181P (on ENST00000338858 / NM_001288821.1; = p.S161P on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- PARD3 | c.1249T>G p.S417A | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- PXMP4 | c.234_241del p.A79Cfs*40 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- RBM27 | c.739C>G p.H247D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- RUBCN | c.2567C>A p.T856N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2
- TP53BP1 | c.1126dup p.I376Nfs*4 | Frame Shift Ins (INS) | VAF 10/41 reads (24%) | called by mutect2, pindel, varscan2
- WAPL | c.2055T>G p.C685W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ZNF234 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF521 | c.3812T>A p.L1271* | Nonsense Mutation (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- ABCB4 | c.2166G>A p.G722= | Silent (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- CLDN7 | c.348C>T p.A116= | Silent (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- COL6A3 | c.6225G>A p.P2075= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs368711215; called by muse, mutect2, varscan2
- CTSW | c.105G>A p.P35= | Silent (SNP) | VAF 28/97 reads (29%) | catalogued as rs559592357; called by muse, mutect2, varscan2
- KRAS | c.180T>A p.G60= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs397517037, COSV55499291, COSV55523567, COSV99782811; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NGEF | c.1239C>T p.F413= | Silent (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- ZNF792 | c.531G>A p.R177= | Silent (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- CTSL3P | n.293G>T | RNA (SNP) | VAF 4/54 reads (7%) | called by muse, mutect2
